Somatic mutation profile of tumor specimen TCGA-CG-4300-01A (aliquot TCGA-CG-4300-01A-01D-1158-08) from TCGA case TCGA-CG-4300, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 79.7 years (29,128 days).
Specimen TCGA-CG-4300-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6a20ecb-335b-4ebd-a75d-7d318973ee67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4300-10A (Blood Derived Normal), aliquot TCGA-CG-4300-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c09b208d-2e7b-4116-9580-27f20f4c7e67

The open-access MAF lists 109 somatic variants for this specimen: 85 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 21, Nonsense Mutation 6, Splice Site 4, Frame Shift Del 3, In Frame Del 2, Nonstop Mutation 2, Intron 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.1888T>G p.F630V | Missense Mutation (SNP) | VAF 25/382 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100957836, COSV100958101, COSV66328724; called by muse, mutect2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 40/88 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ABT1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV51292271; called by muse, mutect2
- ADCY7 | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs766694531, COSV54269494; called by muse, mutect2, varscan2
- ALDH1L1 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs755365962, COSV99856327; called by muse, mutect2, varscan2
- ALMS1 | c.6791C>T p.T2264I | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1311314570, COSV52517594; called by muse, mutect2
- ARHGEF6 | c.1223T>G p.I408S | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV51694341; called by muse, mutect2, varscan2
- ASPM | c.5926A>T p.I1976F | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV54135347; called by muse, mutect2
- ATG9A | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as rs761159469, COSV60134459; called by muse, mutect2, varscan2
- ATXN2L | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57376454; called by muse, mutect2, varscan2
- B4GALT4 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1413926933, COSV63296314; called by muse, mutect2, varscan2
- BANK1 | c.741A>C p.K247N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100535675, COSV59847373; called by muse, mutect2, varscan2
- BAZ2A | c.1580A>G p.E527G | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV51641075; called by muse, mutect2
- C10orf71 | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV60510853; called by muse, mutect2, varscan2
- C6orf201 | c.278T>A p.V93D | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV60988130; called by muse, mutect2, varscan2
- CATSPERE | c.1698T>A p.Y566* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as COSV63679446; called by muse, mutect2, varscan2
- CERT1 | c.876G>T p.M292I (on ENST00000405807 / NM_001130105.1; = p.M164I on NM_005713.3) | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.16); catalogued as COSV54662822; called by muse, mutect2
- CFAP100 | c.1058A>G p.E353G | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV61504083; called by muse, mutect2, varscan2
- CHD2 | c.5084C>A p.S1695Y | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV101244509; called by muse, mutect2
- CHRNA9 | c.1440G>T p.*480Yext*10 | Nonstop Mutation (SNP) | VAF 89/243 reads (37%) | catalogued as COSV59575454; called by muse, mutect2, varscan2
- CNTN1 | c.742T>C p.F248L | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61643460; called by muse, mutect2
- COPB1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1373598124, COSV51449913; called by muse, mutect2
- DIRAS3 | c.240C>A p.C80* | Nonsense Mutation (SNP) | VAF 55/207 reads (27%) | catalogued as rs768829006, COSV63971062; called by muse, mutect2, varscan2
- ELL | c.1789T>C p.Y597H | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53214634; called by muse, mutect2, varscan2
- EXT1 | c.1077G>A p.M359I | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as CD099303, COSV65483145; called by muse, mutect2, varscan2
- FAM131B | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV58372923; called by muse, mutect2
- FAM53C | c.426G>C p.W142C | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53512499; called by muse, mutect2
- FAM83G | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as COSV58760688; called by muse, mutect2, varscan2
- FAR2 | c.24T>G p.Y8* | Nonsense Mutation (SNP) | VAF 53/108 reads (49%) | catalogued as COSV51728445; called by muse, mutect2, varscan2
- FAT3 | c.1631G>A p.R544K | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.155); catalogued as COSV53153625; called by muse, mutect2, varscan2
- HCK | c.1269G>A p.W423* | Nonsense Mutation (SNP) | VAF 24/518 reads (5%) | catalogued as COSV52945801; called by muse, mutect2
- HIVEP2 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773953121, COSV50035924; called by muse, mutect2
- HSPA9 | c.932C>G p.A311G | Missense Mutation (SNP) | VAF 19/302 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51865737; called by muse, mutect2
- IFNW1 | c.557G>T p.R186I | Missense Mutation (SNP) | VAF 87/161 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV101207599, COSV66522296; called by muse, mutect2, varscan2
- KCNT2 | c.2092A>G p.R698G | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs745756373, COSV54091848, COSV54098585; called by muse, mutect2, varscan2
- KRBA1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs767467991, COSV55442502; called by muse, mutect2, varscan2
- LCE2A | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.101); catalogued as rs763307251, COSV64227059; called by muse, mutect2, varscan2
- LRGUK | c.1623G>T p.E541D | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as COSV53641578, COSV99603733; called by muse, mutect2
- LYPD2 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs751446640, COSV63649782; called by muse, mutect2, varscan2
- MAGEA4 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 104/140 reads (74%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs759710688, COSV52342551; called by muse, mutect2, varscan2
- MED17 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.437); catalogued as COSV52602440; called by muse, mutect2, varscan2
- MEIS2 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 35/532 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs748942972, COSV54942046; called by muse, mutect2
- MKI67 | c.8775_8776del p.Q2926Nfs*6 | Frame Shift Del (DEL) | VAF 86/382 reads (23%) | catalogued as rs1173089014; called by pindel, varscan2
- MUC5B | c.3889A>T p.R1297W | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV71594379; called by muse, mutect2, varscan2
- NCOA1 | c.3640G>C p.G1214R | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56050355; called by muse, mutect2
- NSUN2 | c.953A>G p.Y318C | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52956133; called by muse, mutect2
- NYAP2 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as rs760861891, COSV56012875; called by muse, mutect2, varscan2
- OBSCN | c.2441C>T p.P814L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs374032777; called by muse, mutect2, varscan2
- OR5T1 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV57302939; called by muse, mutect2
- OTOF | c.3862G>A p.A1288T (on ENST00000272371 / NM_194248.3; = p.A521T on NM_004802.4) | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs747407421, COSV55510095; called by muse, mutect2, varscan2
- PCDHB13 | c.2320T>G p.F774V | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV53399467; called by muse, mutect2
- PI15 | c.274-1G>T p.X92_splice | Splice Site (SNP) | VAF 29/305 reads (10%) | catalogued as COSV52640402, COSV52643932; called by muse, mutect2
- PLEKHB2 | c.632C>T p.T211M (on ENST00000409279; = p.T210M on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/414 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs990923495, COSV52177342; called by muse, mutect2, varscan2
- PRR14 | c.954T>A p.N318K | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.085); catalogued as COSV54913124; called by muse, mutect2, varscan2
- PTCHD3 | c.2222C>G p.S741* | Nonsense Mutation (SNP) | VAF 5/98 reads (5%) | catalogued as COSV71257176; called by muse, mutect2
- RBM11 | c.573C>A p.H191Q | Missense Mutation (SNP) | VAF 134/600 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1304772212, COSV68748284; called by muse, varscan2
- RMC1 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs747025423, COSV52570390; called by muse, mutect2, varscan2
- RMI2 | c.389T>C p.I130T | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as COSV56964349; called by muse, mutect2
- RPL3 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs11547980, COSV53366236; called by muse, mutect2, varscan2
- SCN11A | c.4612G>T p.A1538S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV56575133, COSV56579457; called by muse, mutect2, varscan2
- SEMA3D | c.2333A>G p.*778Wext*4 | Nonstop Mutation (SNP) | VAF 9/161 reads (6%) | catalogued as COSV52394579, COSV52400241; called by muse, mutect2
- SERPINI2 | c.606T>G p.N202K | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV52988009; called by muse, mutect2, varscan2
- SLC22A12 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as rs1384341957, COSV60572317; called by muse, mutect2, varscan2
- SLC38A1 | c.815A>C p.N272T | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV67064356; called by muse, mutect2, varscan2
- SNPH | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs139099290; called by muse, mutect2, varscan2
- SPRYD7 | c.343A>G p.K115E | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.624); catalogued as COSV62524550; called by muse, mutect2
- THSD7A | c.2208A>C p.K736N | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV70269780; called by muse, mutect2, varscan2
- TMC2 | c.1594-1G>A p.X532_splice | Splice Site (SNP) | VAF 18/606 reads (3%) | catalogued as COSV62656587; called by muse, mutect2
- TMEM64 | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1430539078, COSV69128082; called by muse, mutect2
- TNFSF10 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.573); catalogued as rs138912628, COSV53842395, COSV53843656; called by muse, mutect2
- TRIM46 | c.1828G>A p.G610R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58117422; called by muse, mutect2, varscan2
- TSLP | c.350A>G p.Q117R | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV61292177; called by muse, mutect2
- TXNDC16 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775940793, COSV55986241; called by muse, mutect2, varscan2
- USP20 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.278); catalogued as rs766157763, COSV59617172; called by mutect2, varscan2
- WDR47 | c.2666A>T p.D889V (on ENST00000369962 / NM_001142551.2; = p.D890V on NM_014969.5) | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63059118; called by muse, mutect2, varscan2
- ZNF462 | c.453T>G p.N151K | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV52947302; called by muse, mutect2, varscan2
- ZSWIM8 | c.2186A>G p.Y729C | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67133904; called by muse, mutect2, varscan2
- ELP2 | c.217+3_217+25del p.X73_splice | Splice Site (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel
- FLACC1 | c.1101+1G>A p.X367_splice | Splice Site (SNP) | VAF 9/220 reads (4%) | called by muse, mutect2
- FNTA | c.736_743dup p.G249Tfs*21 | Frame Shift Ins (INS) | VAF 38/163 reads (23%) | called by mutect2, varscan2
- HPSE | c.930del p.L311* | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- NIFK | c.12_29del p.F4_P10delinsL | In Frame Del (DEL) | VAF 18/74 reads (24%) | called by mutect2, pindel, varscan2
- PHF12 | c.133_135del p.K45del | In Frame Del (DEL) | VAF 18/87 reads (21%) | called by mutect2, pindel, varscan2
- TASOR | c.4503del p.D1501Efs*15 (on ENST00000355628 / NM_001365636.2; = p.D1125Efs*15 on NM_015224.3) | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | called by mutect2, pindel, varscan2
- TRIM75P | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- ASMT | c.519C>T p.T173= | Silent (SNP) | VAF 102/190 reads (54%) | catalogued as rs773168368, COSV67109536; called by muse, mutect2, varscan2
- CCDC38 | c.12T>C p.N4= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV60184263; called by muse, mutect2, varscan2
- CFAP52 | c.735G>A p.A245= | Silent (SNP) | VAF 83/280 reads (30%) | catalogued as rs534129407, COSV55346348; called by muse, mutect2, varscan2
- CPSF1 | c.1929C>T p.G643= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs374273379; called by muse, mutect2
- CR1 | c.2400C>T p.A800= | Silent (SNP) | VAF 15/247 reads (6%) | catalogued as rs1423553814; called by muse, mutect2
- DPP6 | c.1926G>A p.E642= (on ENST00000377770 / NM_001364500.2; = p.E580= on NM_001936.5) | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV59634701; called by muse, mutect2, varscan2
- ESPL1 | c.699G>A p.V233= | Silent (SNP) | VAF 65/429 reads (15%) | catalogued as COSV57761717; called by muse, mutect2, varscan2
- GABRG2 | c.856A>C p.R286= (on ENST00000361925 / NM_001375343.1; = p.R246= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV62715776; called by muse, mutect2
- GPATCH3 | c.801T>C p.D267= | Silent (SNP) | VAF 22/346 reads (6%) | catalogued as COSV64652487; called by muse, mutect2
- IFNA14 | c.303T>C p.D101= | Silent (SNP) | VAF 11/255 reads (4%) | catalogued as COSV66516344; called by muse, mutect2
- KEAP1 | c.285C>A p.A95= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV50610622; called by muse, mutect2, varscan2
- KRT13 | c.780G>A p.V260= | Silent (SNP) | VAF 388/6082 reads (6%) | catalogued as COSV55840977; called by muse, mutect2
- NME5 | c.489A>G p.L163= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV54523681; called by muse, mutect2, varscan2
- OR2F1 | c.87C>T p.V29= | Silent (SNP) | VAF 21/504 reads (4%) | catalogued as COSV67331827; called by muse, mutect2
- PEAK1 | c.969T>C p.N323= | Silent (SNP) | VAF 9/162 reads (6%) | catalogued as COSV56940542; called by muse, mutect2
- PLCE1 | c.4209C>T p.I1403= | Silent (SNP) | VAF 18/202 reads (9%) | catalogued as rs145456568; called by muse, mutect2
- RAB10 | c.477C>T p.I159= | Silent (SNP) | VAF 43/295 reads (15%) | catalogued as rs201936806, COSV53091876; called by muse, mutect2, varscan2
- RASSF8 | c.375G>T p.P125= | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as COSV51454804; called by muse, mutect2
- RELN | c.8115T>G p.T2705= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV59024397; called by muse, mutect2, varscan2
- REPS1 | c.1143G>A p.G381= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV57812996; called by muse, mutect2, varscan2
- USP7 | c.288A>G p.P96= | Silent (SNP) | VAF 108/211 reads (51%) | catalogued as rs773674539, COSV61216523; called by muse, mutect2, varscan2
- AP1M1 | c.-2T>C | 5'UTR (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99358066; called by muse, mutect2, varscan2
- NOP56 | c.209-143C>A | Intron (SNP) | VAF 79/283 reads (28%) | catalogued as COSV100249894, COSV61389118; called by muse, mutect2, varscan2
- SORCS1 | c.3371+244G>A | Intron (SNP) | VAF 6/94 reads (6%) | catalogued as COSV99542032; called by muse, mutect2
